MMRF case MMRF_1260 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0e0de479-ea3d-4472-a716-6f7fd7144d2c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Dead; Days to death: 1,100 days (3.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.3 years (30,777 days); ISS stage: I; Days to last known disease status: 1,100 days (3.0 years); Days to last follow up: 1,100 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 142 days; Days to treatment end: 1,038 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 142 days; Days to treatment end: 226 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,100.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 1): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 41 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 3.12 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 4.62 ×10⁹/L; Absolute Neutrophil 3.88 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 8.9 g/dL; Glucose 4.57 mmol/L.
- Day 78 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.919 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.979 mg/dL; Beta 2 Microglobulin 0.8 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 1.56 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 7.59 mmol/L.
- Day 182 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 2.68 ×10⁹/L; Absolute Neutrophil 1.69 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 6.6 mmol/L.
- Day 254 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.805 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 3.94 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 6.22 mmol/L.
- Day 344 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 5.32 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 6.11 mmol/L.
- Day 456 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.91 ×10⁹/L; Absolute Neutrophil 3.63 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 7.43 mmol/L.
- Day 539 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Hemoglobin 6.63 mmol/L; Leukocytes 5.51 ×10⁹/L; Absolute Neutrophil 3.87 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 6.49 mmol/L.
- Day 632 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.14 ×10⁹/L; Absolute Neutrophil 3.74 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 8.36 mmol/L.
- Day 721 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.717 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 5.13 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 7.15 mmol/L.
- Day 814 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 5.23 ×10⁹/L; Absolute Neutrophil 3.73 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 898 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.999 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 5.82 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.38 mmol/L.
- Day 996 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Hemoglobin 6.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.37 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 1,052 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.92 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 2.92 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 172 ×10⁹/L.

Other clinical attributes
- Day -8: Weight: 60 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1260_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1260_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
